Surgical pathology report (de-identified scan), TCGA case TCGA-HU-8602, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-8602-01A (Primary Tumor).

██████ – Subject ID: ██████

Stomach, subtotal gastrectomy:

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(+ +)/Muc6(-)/CD10(-)/cERB2(-),G type)

1. Location : lower third, Center at antrum and lesser curvature
2. Gross type : Borrmann type 2 (ulcerofungating)
3. Histologic type : adenocarcinoma, poorly differentiated non-solid (por2)
4. Histologic type by Lauren : diffuse
5. Growth pattern: mixed expanding and infiltrative growth pattern
6. Size : 15.0x8.0cm
7. Depth of invasion : invades serosa (visceral peritoneum) (pT4a)
8. Resection margins and anvil ring : free from carcinoma
safety margins: distal 0.5cm, proximal 3.5cm
9. Lymph node metastasis : no metastasis in 61 regional lymph nodes (pN0)
(lesser curvature 0/37, greater curvature 0/24)
10. Lymphatic invasion : present, mild
11. Venous invasion : not identified
12. Perineural invasion : not identified
13. Other finding: jejunum – no tumor.

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

Source: NCI Genomic Data Commons file 1ecc9263-4cc9-43d8-a66b-1cbabaddeb12 (TCGA-HU-8602.BBF60878-BD60-45DD-B332-2F544FEE21A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).